Somatic mutation profile of tumor specimen HCM-BROD-0561-C43-06A (aliquot HCM-BROD-0561-C43-06A-11D-A79L-36) from HCMI case HCM-BROD-0561-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.4 years (23,161 days).
Specimen HCM-BROD-0561-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0939fd8-67d1-4a2c-a786-080c52b27bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0561-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0561-C43-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93f47a3c-dc25-49f2-a739-b96e9fe3a5f5

The open-access MAF lists 727 somatic variants for this specimen: 488 protein-altering or splice-affecting, 216 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 437, Silent 216, Nonsense Mutation 35, Intron 13, Splice Region 7, 3'UTR 3, Splice Site 3, 5'Flank 3, Frame Shift Del 3, 5'UTR 2, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 183/413 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.1186A>T p.I396F | Missense Mutation (SNP) | VAF 151/357 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1264397376; called by muse, mutect2, varscan2
- ABCD3 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1202340033, COSV64644738; called by muse, mutect2, varscan2
- ABCG2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 178/456 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs769012528, COSV99418745, COSV99419844; called by muse, mutect2, varscan2
- ABHD15 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 234/532 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145964335; called by muse, mutect2, varscan2
- ABHD15 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 231/529 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265822616; called by muse, mutect2, varscan2
- AC100868.1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 146/964 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as rs761441732, COSV51845748; called by muse, mutect2, varscan2
- ACKR3 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 246/539 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs753186392; called by muse, mutect2, varscan2
- ACTN2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 182/409 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1240148760; called by muse, varscan2
- ADAMTSL4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 215/474 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54996195; called by muse, mutect2, varscan2
- ADCY1 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52040303; called by muse, mutect2, varscan2
- ADGRB2 | c.4678C>T p.R1560* (on ENST00000373658 / NM_001364857.2; = p.R1559* on NM_001294335.2) | Nonsense Mutation (SNP) | VAF 189/429 reads (44%) | catalogued as rs976961418; called by muse, varscan2
- ADGRG6 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 155/216 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99749058; called by muse, mutect2, varscan2
- AHNAK | c.15782C>T p.S5261F | Missense Mutation (SNP) | VAF 206/458 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771792360; called by muse, mutect2, varscan2
- ALMS1 | c.7352C>T p.S2451L | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV52502907; called by muse, varscan2
- ALS2 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51885616; called by muse, mutect2, varscan2
- AMPD3 | c.724G>A p.E242K (on ENST00000396553 / NM_001025389.2; = p.E251K on NM_000480.3) | Missense Mutation (SNP) | VAF 203/488 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs751459310; called by muse, mutect2, varscan2
- AMPD3 | c.1255C>T p.R419W (on ENST00000396553 / NM_001025389.2; = p.R428W on NM_000480.3) | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs374394284; called by muse, mutect2, varscan2
- ANKFN1 | c.3457G>A p.G1153S (on ENST00000653862; = p.G1006S on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/429 reads (46%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.021); catalogued as rs767680949; called by muse, mutect2, varscan2
- ANKRD18A | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1445234878; called by muse, mutect2, varscan2
- ANTXR1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58021757; called by muse, mutect2, varscan2
- APOH | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1567740983, COSV52773316; called by muse, mutect2, varscan2
- ARAP1 | c.953C>T p.P318L (on ENST00000393609 / NM_001040118.2; = p.P73L on NM_015242.4) | Missense Mutation (SNP) | VAF 288/676 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746589096; called by muse, mutect2, varscan2
- ARHGAP21 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 149/198 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs200969279, COSV100255604; called by muse, mutect2, varscan2
- ASNSD1 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53624049; called by muse, mutect2, varscan2
- ASXL3 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 167/396 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs770935265, COSV52472441; called by muse, mutect2, varscan2
- AXL | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 162/473 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs536724919, COSV56567831; called by muse, mutect2, varscan2
- BFAR | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 131/377 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1297792907, COSV55493943; called by muse, mutect2, varscan2
- BICRA | c.3620C>T p.S1207L | Missense Mutation (SNP) | VAF 200/463 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs758950481; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 128/520 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BRDT | c.1036A>C p.M346L | Missense Mutation (SNP) | VAF 153/356 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV62865659, COSV62866039; called by muse, mutect2, varscan2
- C19orf18 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780592836, COSV100071660; called by muse, mutect2, varscan2
- C3orf33 | c.245G>A p.R82Q (on ENST00000340171 / NM_001308229.2; = p.R39Q on NM_173657.2) | Missense Mutation (SNP) | VAF 111/140 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as rs759430996; called by muse, mutect2, varscan2
- CACNA1C | c.3140G>A p.G1047E | Missense Mutation (SNP) | VAF 135/259 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59702154; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, mutect2, varscan2
- CALCRL | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.125); catalogued as COSV101131038, COSV66475467; called by muse, mutect2, varscan2
- CCDC146 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV53549163; called by muse, mutect2, varscan2
- CCRL2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 205/455 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs755483032, COSV99050934; called by muse, mutect2, varscan2
- CCSER1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 163/368 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760274993, COSV100395785; called by muse, mutect2, varscan2
- CDH17 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 175/1077 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50334035; called by muse, mutect2
- CELSR3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 197/474 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50850368; called by muse, mutect2, varscan2
- CENPX | c.36+1G>A p.X12_splice | Splice Site (SNP) | VAF 434/1102 reads (39%) | catalogued as COSV100141973; called by muse, mutect2, varscan2
- CENPX | c.36G>A p.K12= | Splice Region (SNP) | VAF 437/1112 reads (39%) | catalogued as rs1568011056, COSV60713021; called by muse, mutect2, varscan2
- CFAP61 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 170/425 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866241136; called by muse, mutect2, varscan2
- CHGB | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2, varscan2
- CHST13 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 288/355 reads (81%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.688); catalogued as rs1161509789; called by muse, mutect2, varscan2
- CLEC18C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 214/1062 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1267437901, COSV100032225; called by muse, mutect2
- CMYA5 | c.11542G>A p.G3848R | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs888397347; called by muse, mutect2, varscan2
- COL3A1 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV58581291; called by muse, mutect2, varscan2
- COL4A1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 173/434 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV101011079; called by muse, mutect2, varscan2
- CPPED1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 209/445 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1175173911; called by muse, mutect2, varscan2
- CR1L | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 184/434 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV54324849; called by muse, mutect2, varscan2
- CRY2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 161/334 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs199709255, COSV69888765; called by muse, mutect2, varscan2
- CRYBG2 | c.4559C>T p.S1520F | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424264394; called by muse, mutect2, varscan2
- CUX1 | c.1787G>A p.W596* | Nonsense Mutation (SNP) | VAF 185/441 reads (42%) | catalogued as rs1554518634; called by muse, mutect2, varscan2
- CWF19L2 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs776508638; called by muse, mutect2, varscan2
- CYLC1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 182/202 reads (90%) | SIFT tolerated (0.63); PolyPhen benign (0.17); catalogued as COSV100254841; called by muse, mutect2, varscan2
- CYP19A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs770120065, COSV53057383; called by muse, mutect2, varscan2
- CYP2C18 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 317/354 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142667327, COSV53674528; called by muse, mutect2, varscan2
- CYP4F2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs1418098189, COSV55617077; called by muse, mutect2, varscan2
- CYP4X1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV64150212; called by muse, mutect2, varscan2
- DDX4 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61756511; called by muse, mutect2, varscan2
- DHDH | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs370625899; called by muse, mutect2, varscan2
- DNAH3 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 105/256 reads (41%) | catalogued as rs1567809414, COSV54521739; called by muse, mutect2, varscan2
- DNAH6 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs963087684; called by muse, mutect2, varscan2
- DNASE1L3 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99041552; called by muse, mutect2, varscan2
- DPRX | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 115/318 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV100934094; called by muse, mutect2, varscan2
- DSC3 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs866687286, COSV100844559; called by muse, mutect2, varscan2
- DSCAM | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 180/448 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV68020410; called by muse, mutect2, varscan2
- DSCAM | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 163/369 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV101261697; called by muse, mutect2, varscan2
- DUOX1 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs767305748, COSV58479095; called by muse, mutect2, varscan2
- DZIP1 | c.1783C>T p.R595* (on ENST00000347108; = p.R576* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 168/400 reads (42%) | catalogued as rs756109756, COSV61263776; called by muse, mutect2, varscan2
- E2F4 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 171/203 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs746229580, COSV58875098; called by muse, mutect2, varscan2
- EFCAB9 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 143/347 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs1200203222; called by muse, mutect2, varscan2
- EFR3B | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 237/522 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53119301; called by muse, mutect2, varscan2
- EIF4G2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs1442776478, COSV101151049, COSV60596497; called by muse, mutect2, varscan2
- EIF4G3 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs372089216; called by muse, mutect2, varscan2
- EMP1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 206/588 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs767672209; called by muse, mutect2, varscan2
- EP300 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 168/546 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV54347351, COSV99606956; called by muse, mutect2, varscan2
- EPB41L5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs199753897; called by muse, mutect2, varscan2
- ETV7 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 121/438 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60317132; called by muse, mutect2, varscan2
- EVI5 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773804312; called by muse, mutect2, varscan2
- EZHIP | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 246/283 reads (87%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.78); catalogued as rs781925893, COSV57955047; called by muse, mutect2, varscan2
- FAM131B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 193/522 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV58369943; called by muse, mutect2, varscan2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 155/1095 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 574/734 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM98A | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 355/819 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.903); catalogued as COSV53212104; called by muse, mutect2, varscan2
- FASN | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 347/745 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV60756776; called by muse, mutect2, varscan2
- FLYWCH2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 199/857 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs376968137; called by muse, mutect2, varscan2
- FLYWCH2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 199/860 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV53559011; called by muse, mutect2, varscan2
- FMN2 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 96/553 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV60445800; called by muse, varscan2
- GABRP | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.79); catalogued as rs1374031679; called by muse, mutect2, varscan2
- GAPT | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 211/422 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs370924428; called by muse, mutect2, varscan2
- GATA6 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 331/706 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs563978220; called by muse, mutect2, varscan2
- GNGT2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 115/287 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as rs901763365; called by muse, mutect2, varscan2
- GPC4 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 185/208 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63697091; called by muse, mutect2, varscan2
- GPR142 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 281/605 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100171000; called by muse, mutect2, varscan2
- GPR148 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 192/487 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1415084072; called by muse, mutect2, varscan2
- GSDME | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 146/354 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61652298; called by muse, mutect2, varscan2
- GTF3C1 | c.4484C>T p.P1495L | Missense Mutation (SNP) | VAF 162/380 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748133139; called by muse, mutect2, varscan2
- H2AC1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 230/651 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV51237789; called by muse, mutect2, varscan2
- HAX1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.428); catalogued as rs1342223114; called by muse, mutect2, varscan2
- HEATR9 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 267/570 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1046265812; called by muse, mutect2, varscan2
- HID1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs141799560; called by muse, mutect2, varscan2
- HSFX2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 178/410 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs1464113515; called by muse, mutect2, varscan2
- HTRA3 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 184/413 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs765049863, COSV56471190; called by muse, mutect2, varscan2
- HYDIN | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868676049, COSV99865696; called by muse, mutect2, varscan2
- IGHV3-13 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 199/530 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as rs568429833; called by muse, mutect2, varscan2
- IL1B | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV54522820, COSV99641940; called by muse, mutect2, varscan2
- IPO13 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs1557632190; called by muse, mutect2, varscan2
- ITGA1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50901887; called by muse, mutect2, varscan2
- ITGB4 | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 242/560 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52333019; called by muse, mutect2, varscan2
- ITGB4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 129/303 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs886053409, COSV52322502, COSV52324788, COSV52332573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2, varscan2
- KCNH5 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59757775; called by muse, mutect2, varscan2
- KCNQ3 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 923/1144 reads (81%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs766760025; called by mutect2, varscan2
- KIF3B | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 162/379 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs769441232; called by muse, mutect2, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KLHL4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 182/197 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs190477338, COSV64139169; called by muse, mutect2, varscan2
- LAMB4 | c.3053C>T p.T1018I | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs754812469; called by muse, mutect2, varscan2
- LCP2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1197342170; called by muse, mutect2, varscan2
- LCT | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201664009, COSV51545585; called by muse, mutect2, varscan2
- LINGO2 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430074; called by muse, mutect2, varscan2
- LMAN1L | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1191894246; called by muse, mutect2, varscan2
- LRRC72 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 99/265 reads (37%) | catalogued as rs780558703, COSV69130958; called by muse, mutect2, varscan2
- LTBP2 | c.4851G>A p.W1617* | Nonsense Mutation (SNP) | VAF 155/412 reads (38%) | catalogued as COSV56211672; called by muse, mutect2, varscan2
- LTBP2 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 257/615 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs763665239, COSV100001208; called by muse, mutect2, varscan2
- LY6K | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 882/1094 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs1172467075, COSV52832110; called by muse, mutect2, varscan2
- MBD5 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs749574412, COSV68698339; called by muse, mutect2, varscan2
- MECOM | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 172/218 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761171278, COSV72110504; called by muse, mutect2, varscan2
- MED14 | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 188/212 reads (89%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61357419; called by muse, mutect2, varscan2
- MED26 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 263/531 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467486702; called by muse, mutect2, varscan2
- MGAM | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 179/422 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101516333; called by muse, mutect2, varscan2
- MGAM2 | c.3306G>A p.M1102I | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs867532916, COSV101522919; called by muse, mutect2, varscan2
- MIB1 | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 144/370 reads (39%) | catalogued as rs1555694075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP16 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 214/1243 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs553868301, COSV54154651; called by muse, mutect2, varscan2
- MPDZ | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375346024; called by muse, mutect2, varscan2
- MTMR8 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 258/293 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs775189398; called by muse, mutect2, varscan2
- MTSS1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 524/673 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1361280992, COSV61494478; called by muse, mutect2
- MUC16 | c.25978C>T p.P8660S | Missense Mutation (SNP) | VAF 216/519 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.065); catalogued as rs1568797505; called by muse, mutect2, varscan2
- MUC16 | c.25187C>T p.S8396F | Missense Mutation (SNP) | VAF 199/461 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV101198768; called by muse, mutect2, varscan2
- MUC16 | c.14974G>A p.D4992N | Missense Mutation (SNP) | VAF 166/385 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.093); catalogued as COSV67492491; called by muse, mutect2, varscan2
- MUC20 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 69/448 reads (15%) | SIFT tolerated, low confidence (0.1); catalogued as rs1425538927; called by muse, varscan2
- MYCL | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 185/448 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs1312202445; called by muse, mutect2, varscan2
- MYL2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 168/441 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57405879; called by muse, mutect2, varscan2
- MYO3B | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866879141, COSV100509399, COSV58714099; called by muse, mutect2, varscan2
- MYO9B | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 240/598 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs748214669; called by muse, mutect2, varscan2
- NAGA | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 219/855 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs773683396; called by muse, mutect2, varscan2
- NEXMIF | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 165/181 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs267606511, COSV50045459, COSV99280638; called by muse, mutect2, varscan2
- NF1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62217982; called by muse, mutect2, varscan2
- NFKBID | c.523C>T p.P175S (on ENST00000396901; = p.P327S on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/423 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV61728273; called by muse, mutect2, varscan2
- NLRP4 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 181/421 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1314897163; called by muse, mutect2, varscan2
- NME8 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52251728; called by muse, mutect2, varscan2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 354/739 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by muse, mutect2, varscan2
- OCM2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 156/369 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747093318, COSV57535115; called by muse, mutect2, varscan2
- OOSP1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 172/411 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1000134920, COSV67527450; called by muse, mutect2, varscan2
- OPRD1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 316/698 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as rs139895939; called by muse, varscan2
- OR10X1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 151/501 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100936720; called by muse, mutect2, varscan2
- OR11A1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 144/541 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV65820757; called by muse, mutect2, varscan2
- OR13A1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 110/147 reads (75%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65573428; called by muse, mutect2, varscan2
- OR2F1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 216/547 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67332099; called by muse, mutect2, varscan2
- OR2Y1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 171/396 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV57137608, COSV57137765; called by muse, mutect2, varscan2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 144/274 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR5M8 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV59116574; called by muse, mutect2, varscan2
- OSBPL6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 162/371 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.165); catalogued as COSV51920128, COSV99506400; called by muse, mutect2, varscan2
- OSM | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 253/602 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs200481037; called by muse, mutect2, varscan2
- OTOF | c.3440G>A p.R1147Q (on ENST00000272371 / NM_194248.3; = p.R400Q on NM_004802.4) | Missense Mutation (SNP) | VAF 189/439 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs369188910; called by muse, mutect2, varscan2
- PAPPA | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775634573, COSV60282314; called by muse, mutect2, varscan2
- PCDH18 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 163/200 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100787463; called by muse, mutect2, varscan2
- PCDH9 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 121/380 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60532348, COSV60586640; called by muse, mutect2, varscan2
- PCDHA11 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as rs745813666, COSV56485626; called by muse, mutect2, varscan2
- PCLO | c.12768G>A p.M4256I | Missense Mutation (SNP) | VAF 143/332 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1362193454, COSV100433963, COSV61630371; called by muse, mutect2, varscan2
- PCLO | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 180/407 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as rs745329573; called by muse, mutect2, varscan2
- PDILT | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 148/406 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1373532778, COSV56703412; called by muse, mutect2, varscan2
- PIK3C3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV56275479; called by muse, mutect2, varscan2
- PIP5K1A | c.542C>T p.S181F (on ENST00000368888 / NM_001135638.2; = p.S168F on NM_003557.3) | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62958287; called by muse, mutect2, varscan2
- PKD1L3 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 180/211 reads (85%) | catalogued as rs1223335178; called by muse, mutect2, varscan2
- PLAAT3 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1490350309; called by muse, mutect2, varscan2
- PLCE1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 293/325 reads (90%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); catalogued as COSV53369010, COSV99593235; called by muse, mutect2, varscan2
- PRB3 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 178/676 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs148496066; called by muse, varscan2
- PRDM1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 209/268 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1385182753, COSV64844396; called by muse, mutect2, varscan2
- PRKACG | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 211/467 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV55253800; called by muse, mutect2, varscan2
- PRKAR1B | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 228/279 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV64319132; called by muse, mutect2, varscan2
- PTCHD3 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 194/225 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0.365); catalogued as rs868028770, COSV101438955; called by muse, mutect2, varscan2
- PTGS1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 171/346 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV56293163; called by muse, mutect2, varscan2
- PTPRF | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 336/752 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17849128; called by muse, varscan2
- RAB3IP | c.527G>A p.R176Q (on ENST00000550536 / NM_175623.4; = p.R160Q on NM_022456.5) | Missense Mutation (SNP) | VAF 99/125 reads (79%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as rs756835019, COSV56082842, COSV56085195; called by muse, mutect2, varscan2
- RBL2 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 118/153 reads (77%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); catalogued as rs77016789; called by muse, mutect2, varscan2
- RBPJL | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 132/392 reads (34%) | catalogued as rs756771074, COSV59213830; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RICTOR | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 150/426 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs980024517, COSV57125411; called by muse, varscan2
- RIMBP2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 231/494 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs1248114269, COSV55478093, COSV55481546; called by muse, mutect2, varscan2
- RIMS2 | c.2729G>A p.R910Q (on ENST00000666250 / NM_001348490.2; = p.R718Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/634 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771535119, COSV51676113; called by muse, mutect2, varscan2
- ROS1 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 88/109 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185167609; called by muse, mutect2, varscan2
- RP1 | c.5069C>T p.S1690L | Missense Mutation (SNP) | VAF 162/1078 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs750964056, COSV55129263; called by muse, mutect2
- RP1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 234/772 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs751446958; called by muse, mutect2, varscan2
- RUNDC3B | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 140/371 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100406927; called by muse, varscan2
- RYR3 | c.12975G>A p.Q4325= (on ENST00000389232; = p.Q4326= on NM_001036.6) | Splice Region (SNP) | VAF 81/182 reads (45%) | catalogued as COSV101213054; called by muse, mutect2, varscan2
- SCN5A | c.4321G>A p.E1441K (on ENST00000333535 / NM_198056.3; = p.E1440K on NM_000335.5) | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as CM100727, COSV100349357; called by muse, mutect2, varscan2
- SERPINA11 | c.915C>T p.P305= | Splice Region (SNP) | VAF 110/255 reads (43%) | catalogued as rs1477080621; called by muse, mutect2, varscan2
- SERPINB4 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 128/334 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61985829; called by muse, mutect2, varscan2
- SEZ6L2 | c.1027C>T p.P343S (on ENST00000308713 / NM_001114099.3; = p.P273S on NM_012410.4) | Missense Mutation (SNP) | VAF 147/500 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1057335935; called by muse, mutect2, varscan2
- SIMC1 | c.254C>T p.S85F (on ENST00000443967 / NM_001308196.1; = p.S104F on NM_001308195.2) | Missense Mutation (SNP) | VAF 202/434 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV100365228; called by muse, mutect2, varscan2
- SLC30A8 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 729/951 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs753601826; called by muse, mutect2, varscan2
- SLC4A9 | c.2377G>A p.E793K (on ENST00000507527 / NM_001258428.2; = p.E769K on NM_031467.3) | Missense Mutation (SNP) | VAF 164/375 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764257656, COSV50189820; called by muse, mutect2, varscan2
- SLC5A11 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 155/378 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1426701225; called by muse, mutect2, varscan2
- SLC8A3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 171/432 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs148642634; called by muse, mutect2, varscan2
- SNX21 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 316/733 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as rs775236284; called by muse, mutect2, varscan2
- SPANXN4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 165/188 reads (88%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1031927543, COSV100980951; called by muse, mutect2, varscan2
- SPATA31D1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 211/488 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs368073850; called by muse, mutect2, varscan2
- SPHKAP | c.4379C>T p.S1460L | Missense Mutation (SNP) | VAF 173/380 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs368612893, COSV60876685; called by muse, mutect2, varscan2
- SPHKAP | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 177/412 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs760510406, COSV60893705; called by muse, mutect2, varscan2
- SPRR3 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 194/472 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV54878872; called by muse, mutect2, varscan2
- SPTA1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 396/635 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63752052; called by muse, mutect2, varscan2
- TAL1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 272/627 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs765173173; called by muse, mutect2, varscan2
- TEP1 | c.5839C>T p.R1947* | Nonsense Mutation (SNP) | VAF 186/409 reads (45%) | catalogued as rs200869389; called by muse, mutect2, varscan2
- TGM1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 194/454 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.3); catalogued as rs201379408, COSV99253270; called by muse, mutect2, varscan2
- THOC3 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs774666886; called by muse, mutect2, varscan2
- TIMD4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 124/291 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs867787194; called by muse, mutect2, varscan2
- TINAG | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs771554711, COSV52506168; called by muse, mutect2, varscan2
- TLL1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs150728189, COSV50304665; called by muse, mutect2, varscan2
- TLR2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 158/375 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605411; called by muse, mutect2, varscan2
- TMEM260 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 319/525 reads (61%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.749); catalogued as rs961346366; called by muse, mutect2, varscan2
- TMPPE | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 200/453 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs1365997473, COSV56566058; called by muse, mutect2, varscan2
- TNFRSF11B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 118/949 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs202090603, COSV52071162; called by muse, mutect2, varscan2
- TNN | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs756576017, COSV53429664; called by muse, varscan2
- TNRC18 | c.5276C>T p.S1759F | Missense Mutation (SNP) | VAF 235/521 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1333874250; called by muse, mutect2, varscan2
- TPTE | c.796G>A p.E266K (on ENST00000618007 / NM_199261.4; = p.E248K on NM_199259.4) | Missense Mutation (SNP) | VAF 103/347 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1328516038; called by muse, mutect2, varscan2
- TRAT1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 223/267 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV55469879, COSV55470893; called by muse, mutect2, varscan2
- TRERF1 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 280/952 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV61674258; called by muse, mutect2, varscan2
- TRGC1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 106/624 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1052400124; called by muse, mutect2
- TRPM3 | c.2845G>A p.D949N (on ENST00000357533 / NM_001366142.2; = p.D792N on NM_020952.6) | Missense Mutation (SNP) | VAF 197/457 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62580612; called by muse, mutect2, varscan2
- TRPV6 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 270/611 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV63892080; called by muse, mutect2, varscan2
- TTN | c.32326G>A p.E10776K (on ENST00000591111; = p.E9849K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/309 reads (38%) | PolyPhen probably damaging (0.991); catalogued as rs1223983021, COSV59862637; called by muse, mutect2
- TUBG1 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 199/512 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111345251; called by muse, mutect2, varscan2
- UBR4 | c.10000G>A p.A3334T | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs766096673; called by muse, mutect2, varscan2
- USP4 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 116/271 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs758676462; called by muse, mutect2, varscan2
- VCX | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 131/608 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1569093120; called by muse, varscan2
- ZBP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs764212417, COSV100472931; called by muse, mutect2, varscan2
- ZC3H11B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1281222562; called by muse, mutect2, varscan2
- ZC3H13 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 167/352 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760598611, COSV104387510, COSV54457977; called by muse, mutect2, varscan2
- ZMYM3 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 350/404 reads (87%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs779781647; called by muse, mutect2, varscan2
- ZNF134 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 171/394 reads (43%) | catalogued as rs745775901, COSV68696526; called by muse, mutect2, varscan2
- ZNF208 | c.3319C>T p.H1107Y | Missense Mutation (SNP) | VAF 148/198 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs267605384; called by muse, mutect2, varscan2
- ZNF43 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 109/135 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1355975743, COSV61685142; called by muse, mutect2, varscan2
- ZNF432 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 243/510 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1298344417, COSV55415218; called by muse, mutect2, varscan2
- ZNF479 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 162/410 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs782624607; called by muse, mutect2, varscan2
- ZNF696 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 686/859 reads (80%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.713); catalogued as rs1371700038; called by muse, mutect2, varscan2
- ZNF699 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs781646738, COSV58027108; called by muse, mutect2, varscan2
- ZNF804A | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1465760741, COSV56470507; called by muse, mutect2, varscan2
- ZNF827 | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 165/403 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101061221; called by muse, mutect2, varscan2
- ZNF835 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 342/750 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV73379159; called by muse, mutect2
- ZNF865 | c.2327_2350del p.A776_G783del | In Frame Del (DEL) | VAF 176/606 reads (29%) | catalogued as rs1448414892; called by mutect2, varscan2
- A3GALT2 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.413); called by muse, varscan2
- ABCA12 | c.6117G>A p.M2039I (on ENST00000272895 / NM_173076.3; = p.M1721I on NM_015657.3) | Missense Mutation (SNP) | VAF 126/235 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ABCG1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 190/396 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AC099489.1 | c.1964C>A p.T655K | Missense Mutation (SNP) | VAF 198/446 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by muse, mutect2
- AC104389.6 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ADAMTS10 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 212/463 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ADAMTS16 | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA1B | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- AKAP13 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 169/384 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP4 | c.2513T>G p.V838G | Missense Mutation (SNP) | VAF 251/279 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ALMS1 | c.28_35delinsACCGCGCGGGA p.G10_L12delinsTARE | In Frame Ins (INS) | VAF 6/74 reads (8%) | called by muse*, mutect2*, pindel, varscan2*
- ALMS1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ALOXE3 | c.1686T>C p.G562= | Splice Region (SNP) | VAF 79/108 reads (73%) | called by muse, mutect2, varscan2
- ANKRD24 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 207/459 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKS1B | c.2625G>A p.K875= (on ENST00000547776 / NM_152788.4; = p.K101= on NM_020140.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 122/144 reads (85%) | called by muse, mutect2, varscan2
- APLP1 | c.1627C>T p.P543S (on ENST00000221891 / NM_001024807.3; = p.P542S on NM_005166.4) | Missense Mutation (SNP) | VAF 179/433 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOB | c.11425C>T p.P3809S | Missense Mutation (SNP) | VAF 176/404 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- APOB | c.10235G>A p.S3412N | Missense Mutation (SNP) | VAF 190/425 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ARHGAP10 | c.1897A>C p.T633P | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 146/198 reads (74%) | SIFT tolerated (0.41); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARSD | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 90/108 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ASXL2 | c.1811T>C p.F604S | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- B3GALT5 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 202/474 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- BARX2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 275/584 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- BECN2 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 203/477 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BIN1 | c.1682G>A p.G561D (on ENST00000316724 / NM_001320642.1; = p.G422D on NM_004305.4) | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.1361C>T p.S454F (on ENST00000254900 / NM_139199.2; = p.S527F on NM_006696.4) | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- BSN | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 256/585 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- C16orf96 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 183/434 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C5AR2 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 320/662 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CA1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 107/640 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1I | c.5243C>T p.A1748V | Missense Mutation (SNP) | VAF 259/1162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CASP3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CC2D1A | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 200/460 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD101 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CD163L1 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 190/571 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD55 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 210/452 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CDSN | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 297/1036 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP104 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 129/344 reads (38%) | called by muse, mutect2, varscan2
- CHL1 | c.856G>A p.E286K (on ENST00000397491 / NM_001253387.1; = p.E302K on NM_006614.4) | Missense Mutation (SNP) | VAF 133/374 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC18B | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLN5 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 333/715 reads (47%) | called by muse, mutect2, varscan2
- CNGB3 | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 162/1097 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CNST | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- COL12A1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL18A1 | c.5137G>C p.A1713P (on ENST00000359759 / NM_130444.3; = p.A1478P on NM_030582.4) | Missense Mutation (SNP) | VAF 304/717 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL20A1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 234/574 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- COL6A2 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 259/620 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CREB3 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 225/515 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CREBBP | c.6923C>T p.P2308L | Missense Mutation (SNP) | VAF 438/692 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CREBBP | c.6922C>T p.P2308S | Missense Mutation (SNP) | VAF 435/690 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRNN | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 273/604 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DDX43 | c.1076T>A p.I359K | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- DDX60L | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 114/337 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DEF6 | c.96G>A p.K32= | Splice Region (SNP) | VAF 120/415 reads (29%) | called by muse, mutect2, varscan2
- DHX34 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLK1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 265/570 reads (46%) | called by muse, mutect2, varscan2
- DNAH1 | c.11407G>A p.D3803N | Missense Mutation (SNP) | VAF 156/393 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH10 | c.2414G>A p.G805E (on ENST00000409039; = p.G744E on NM_207437.3) | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.13162G>A p.G4388R (on ENST00000409039; = p.G4327R on NM_207437.3) | Missense Mutation (SNP) | VAF 207/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.5011G>A p.E1671K | Missense Mutation (SNP) | VAF 164/368 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DNAH7 | c.9073G>A p.E3025K | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB8 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 190/233 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DZIP1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENDOV | c.586-8T>G | Splice Region (SNP) | VAF 587/1334 reads (44%) | called by muse, mutect2, varscan2
- ETV5 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 105/126 reads (83%) | called by muse, mutect2, varscan2
- EYA1 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 125/759 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EYS | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FAM120A | c.2999G>A p.G1000D | Missense Mutation (SNP) | VAF 140/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.11002G>A p.G3668R | Missense Mutation (SNP) | VAF 162/411 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FBLN2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 279/627 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCGR2A | c.140C>T p.P47L (on ENST00000271450 / NM_001136219.3; = p.P46L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/552 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIZ1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 291/717 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKBP1C | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 213/819 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLT4 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 185/421 reads (44%) | called by muse, varscan2
- FSD1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, varscan2
- GPBAR1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 287/634 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPBP1L1 | c.190+1G>A p.X64_splice | Splice Site (SNP) | VAF 79/198 reads (40%) | called by muse, mutect2, varscan2
- GRAMD2A | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 251/512 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GTF3C1 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 161/383 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACE1 | c.1698C>G p.S566R | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HBG2 | c.92+1G>C p.X31_splice | Splice Site (SNP) | VAF 62/290 reads (21%) | called by muse, mutect2
- HCFC1 | c.4448C>T p.A1483V | Missense Mutation (SNP) | VAF 314/353 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- HDAC10 | c.370A>C p.N124H | Missense Mutation (SNP) | VAF 209/470 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC11 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 170/391 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDGFL1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 708/1129 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, varscan2
- HEATR5B | c.3112C>T p.H1038Y | Missense Mutation (SNP) | VAF 156/365 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HECW2 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HIPK4 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 166/590 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HMCN2 | c.14686C>T p.P4896S | Missense Mutation (SNP) | VAF 184/438 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- HSD3B1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ICE1 | c.1689del p.F563Lfs*42 | Frame Shift Del (DEL) | VAF 142/426 reads (33%) | called by mutect2, pindel, varscan2
- IDH3B | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 165/461 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IL1RAPL1 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 216/239 reads (90%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- INPP5E | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 330/785 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INSYN2B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- INTS2 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- IPO5 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ITK | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR3 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 161/571 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB1 | c.1517C>T p.T506I | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KCNC3 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 300/658 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KCNJ2 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 148/352 reads (42%) | called by muse, mutect2, varscan2
- KIAA2012 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 227/470 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KYNU | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- L1TD1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARP1B | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 111/125 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LCORL | c.4565G>A p.R1522K | Missense Mutation (SNP) | VAF 141/297 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMBRD2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LPAR4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 132/144 reads (92%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC3 | c.239del p.P80Rfs*81 | Frame Shift Del (DEL) | VAF 270/734 reads (37%) | called by mutect2, pindel, varscan2
- LRRC53 | c.3154A>G p.T1052A | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRRC75B | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 127/287 reads (44%) | called by muse, mutect2, varscan2
- LRRC75B | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 126/284 reads (44%) | called by muse, mutect2, varscan2
- LTBP2 | c.4850G>A p.W1617* | Nonsense Mutation (SNP) | VAF 158/418 reads (38%) | called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 371/1147 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBD5 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 109/281 reads (39%) | called by muse, mutect2, varscan2
- MDH1B | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 133/276 reads (48%) | called by muse, mutect2, varscan2
- MED26 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 265/533 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF9 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 144/349 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEIOC | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MEOX1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 193/698 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MGA | c.6767T>C p.V2256A (on ENST00000219905 / NM_001164273.1; = p.V2047A on NM_001080541.2) | Missense Mutation (SNP) | VAF 165/395 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MGAM2 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 173/385 reads (45%) | called by muse, mutect2, varscan2
- MGAM2 | c.5632C>T p.P1878S | Missense Mutation (SNP) | VAF 171/407 reads (42%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- MLLT10 | c.3202A>C p.S1068R | Missense Mutation (SNP) | VAF 162/185 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- MOG | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 269/964 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MSH2 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 353/830 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- MSLN | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 274/876 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MTX2 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MUC12 | c.9190G>C p.E3064Q (on ENST00000379442; = p.E2921Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 237/979 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MUC16 | c.42264T>A p.Y14088* | Nonsense Mutation (SNP) | VAF 168/366 reads (46%) | called by muse, mutect2, varscan2
- MUC16 | c.5779C>T p.P1927S | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO15B | c.7949G>A p.G2650E | Missense Mutation (SNP) | VAF 188/465 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.149); called by muse, mutect2
- NCAPG2 | c.2738T>A p.M913K | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NCOA6 | c.2215G>A p.G739R | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIF3L1 | c.109T>G p.L37V (on ENST00000409020 / NM_001369444.1; = p.L10V on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NOS1 | c.1775G>A p.W592* | Nonsense Mutation (SNP) | VAF 176/433 reads (41%) | called by muse, mutect2, varscan2
- NPHS1 | c.2956C>T p.H986Y | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NT5C1B | c.1651A>C p.T551P (on ENST00000359846 / NM_001199086.2; = p.T491P on NM_033253.4) | Missense Mutation (SNP) | VAF 207/507 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK3 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 155/361 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUMA1 | c.5751G>A p.W1917* | Nonsense Mutation (SNP) | VAF 197/500 reads (39%) | called by muse, mutect2, varscan2
- OR2F1 | c.827T>A p.V276D | Missense Mutation (SNP) | VAF 164/418 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- OR4A47 | c.829del p.T277Pfs*4 | Frame Shift Del (DEL) | VAF 153/558 reads (27%) | called by mutect2, pindel, varscan2
- OR6J1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 149/372 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9A4 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 210/458 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH9 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 122/381 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCDHB12 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 104/258 reads (40%) | called by muse, mutect2, varscan2
- PEG3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PGAP4 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 209/449 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PGAP6 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 353/598 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAP6 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 351/602 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PIWIL2 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 156/210 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PKP2 | c.1309A>T p.N437Y | Missense Mutation (SNP) | VAF 286/504 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- PLA2G4D | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PLCG1 | c.1748T>C p.F583S | Missense Mutation (SNP) | VAF 229/514 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG3 | c.3178C>T p.P1060S (on ENST00000394691; = p.P1116S on NM_001308147.2) | Missense Mutation (SNP) | VAF 206/509 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLIN1 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 315/720 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXNA1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 268/346 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PNPLA6 | c.862G>A p.A288T (on ENST00000414982 / NM_001166111.2; = p.A240T on NM_006702.5) | Missense Mutation (SNP) | VAF 215/527 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POM121C | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 410/656 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP1R9B | c.2439T>G p.N813K | Missense Mutation (SNP) | VAF 161/416 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PROKR1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 240/514 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PWWP2B | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 226/277 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PXDN | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 154/375 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- PZP | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 316/531 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBAK | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 152/383 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- RBBP5 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 138/405 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RBMS3 | c.1112C>T p.A371V (on ENST00000383767 / NM_001003793.3; = p.A355V on NM_014483.3) | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- RFTN1 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 213/491 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGS7BP | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RMDN2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 146/319 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RNF180 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 152/380 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- RNF24 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 183/463 reads (40%) | called by muse, mutect2, varscan2
- RPAP2 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 149/344 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPAP2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 151/345 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RUNDC3B | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 140/369 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, varscan2
- SCN11A | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SELENOV | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 201/733 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SENP1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINB11 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 195/485 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPING1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 166/405 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIRT4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLC36A1 | c.344A>C p.D115A | Missense Mutation (SNP) | VAF 167/374 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC5A8 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 209/259 reads (81%) | SIFT tolerated (0.42); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLFN12L | c.1346C>T p.S449F (on ENST00000260908 / NM_001363830.1; = p.S467F on NM_001195790.1) | Missense Mutation (SNP) | VAF 194/437 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SPATA9 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEN | c.7576G>A p.D2526N | Missense Mutation (SNP) | VAF 212/488 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPINK5 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SRD5A3 | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 208/459 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- STAB1 | c.5524G>A p.D1842N | Missense Mutation (SNP) | VAF 177/435 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUCLG2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SVEP1 | c.9173A>G p.H3058R | Missense Mutation (SNP) | VAF 176/419 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYCP1 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYCP2L | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 218/623 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAOK3 | c.2371C>T p.Q791* | Nonsense Mutation (SNP) | VAF 131/313 reads (42%) | called by muse, mutect2, varscan2
- TAP2 | c.1775T>C p.M592T | Missense Mutation (SNP) | VAF 239/699 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TCF12 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 119/301 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TDRD15 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEAD2 | c.908G>A p.W303* | Nonsense Mutation (SNP) | VAF 129/276 reads (47%) | called by muse, mutect2, varscan2
- TENM2 | c.1118G>A p.W373* (on ENST00000518659 / NM_001122679.2; = p.W182* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 192/445 reads (43%) | called by muse, mutect2, varscan2
- TENM4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TFEB | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 495/812 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TLR2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TM2D3 | c.284C>T p.P95L (on ENST00000333202 / NM_078474.3; = p.P69L on NM_025141.3) | Missense Mutation (SNP) | VAF 138/327 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM132C | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 222/485 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM18 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, varscan2
- TMPRSS13 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 180/439 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNKS1BP1 | c.4957C>T p.P1653S | Missense Mutation (SNP) | VAF 156/370 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOGARAM1 | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TRANK1 | c.4302C>A p.F1434L | Missense Mutation (SNP) | VAF 186/407 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM71 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 211/504 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TTN | c.24031C>T p.H8011Y (on ENST00000591111; = p.H7084Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/343 reads (45%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC5A | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 248/568 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP35 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VAT1L | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 109/143 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWCE | c.2746C>T p.L916F | Missense Mutation (SNP) | VAF 236/586 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWDE | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 136/352 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WASHC2C | c.3950C>T p.A1317V (on ENST00000336378; = p.A1296V on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 222/307 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- WASL | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 122/323 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK1 | c.4900C>T p.H1634Y (on ENST00000315939 / NM_018979.4; = p.H1387Y on NM_014823.3) | Missense Mutation (SNP) | VAF 310/547 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- XPO5 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 172/567 reads (30%) | called by muse, mutect2, varscan2
- XYLB | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ZC3H3 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 773/1002 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ZNF233 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF484 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 183/409 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF528 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF658 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ZNF74 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 299/673 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZP2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN23 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 408/657 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZW10 | c.467T>G p.L156* | Nonsense Mutation (SNP) | VAF 105/260 reads (40%) | called by muse, mutect2, varscan2
- ABCC3 | c.831G>A p.G277= | Silent (SNP) | VAF 196/466 reads (42%) | catalogued as COSV53327288; called by muse, mutect2, varscan2
- ABL2 | c.720C>T p.T240= (on ENST00000502732 / NM_007314.4; = p.T225= on NM_005158.5) | Silent (SNP) | VAF 117/267 reads (44%) | called by muse, mutect2, varscan2
- ACOD1 | c.1125G>C p.P375= | Silent (SNP) | VAF 183/378 reads (48%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1014C>T p.S338= | Silent (SNP) | VAF 159/378 reads (42%) | catalogued as COSV53127040; called by muse, mutect2, varscan2
- ADCK2 | c.282C>T p.F94= | Silent (SNP) | VAF 426/928 reads (46%) | catalogued as COSV50782657; called by muse, mutect2, varscan2
- ADGRG4 | c.8712C>T p.L2904= | Silent (SNP) | VAF 165/196 reads (84%) | called by muse, mutect2, varscan2
- AFDN | c.4026T>C p.R1342= | Silent (SNP) | VAF 216/262 reads (82%) | called by muse, mutect2, varscan2
- AFF1 | c.1492C>T p.L498= | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as COSV100320963, COSV57121125; called by muse, mutect2, varscan2
- AHNAK2 | c.5256C>G p.P1752= | Silent (SNP) | VAF 99/436 reads (23%) | called by muse, mutect2, varscan2
- ANKRD17 | c.2493G>A p.Q831= | Silent (SNP) | VAF 189/404 reads (47%) | called by muse, mutect2, varscan2
- APOB | c.1053G>A p.L351= | Silent (SNP) | VAF 143/366 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.2184G>A p.K728= | Silent (SNP) | VAF 190/250 reads (76%) | called by muse, mutect2, varscan2
- ARSD | c.1779C>T p.P593= | Silent (SNP) | VAF 93/110 reads (85%) | called by muse, mutect2, varscan2
- ATP5F1A | c.993C>T p.P331= | Silent (SNP) | VAF 121/284 reads (43%) | catalogued as rs1452723710; called by muse, mutect2, varscan2
- C4orf54 | c.4479G>A p.E1493= | Silent (SNP) | VAF 188/490 reads (38%) | catalogued as rs1274125688; called by muse, mutect2, varscan2
- CACNA1G | c.4734C>A p.S1578= | Silent (SNP) | VAF 184/452 reads (41%) | catalogued as rs767434117, COSV61724511; called by muse, mutect2, varscan2
- CAV3 | c.447G>A p.K149= | Silent (SNP) | VAF 93/287 reads (32%) | catalogued as rs1455578834; called by muse, mutect2, varscan2
- CCDC168 | c.13311G>A p.E4437= | Silent (SNP) | VAF 110/273 reads (40%) | called by muse, mutect2, varscan2
- CEP95 | c.1173T>C p.G391= | Silent (SNP) | VAF 146/256 reads (57%) | called by muse, mutect2, varscan2
- CFAP92 | c.2409C>T p.F803= | Silent (SNP) | VAF 184/242 reads (76%) | called by muse, mutect2, varscan2
- CFAP92 | c.1497G>A p.R499= | Silent (SNP) | VAF 150/201 reads (75%) | called by muse, mutect2, varscan2
- CHGA | c.900C>T p.S300= | Silent (SNP) | VAF 146/341 reads (43%) | called by muse, mutect2, varscan2
- CHRNA1 | c.1155G>A p.K385= (on ENST00000261007 / NM_001039523.3; = p.K360= on NM_000079.4) | Silent (SNP) | VAF 124/301 reads (41%) | catalogued as COSV53684435, COSV99650570; called by muse, mutect2, varscan2
- CIR1 | c.66C>T p.I22= | Silent (SNP) | VAF 125/267 reads (47%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.573C>T p.S191= | Silent (SNP) | VAF 104/131 reads (79%) | called by muse, mutect2, varscan2
- COL4A4 | c.4434C>T p.P1478= | Silent (SNP) | VAF 250/574 reads (44%) | catalogued as rs1343679990; called by muse, mutect2, varscan2
- CP | c.192G>A p.G64= | Silent (SNP) | VAF 87/114 reads (76%) | catalogued as COSV52828957; called by muse, mutect2, varscan2
- CPD | c.1584C>T p.S528= | Silent (SNP) | VAF 133/320 reads (42%) | called by muse, mutect2, varscan2
- CPT1A | c.1062G>A p.L354= | Silent (SNP) | VAF 192/512 reads (38%) | catalogued as rs764880445, COSV99681790; called by muse, mutect2, varscan2
- CRTC2 | c.1066C>T p.L356= | Silent (SNP) | VAF 212/560 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.1824C>T p.I608= | Silent (SNP) | VAF 181/408 reads (44%) | catalogued as COSV53968367; called by muse, mutect2, varscan2
- CTNNB1 | c.765C>T p.A255= | Silent (SNP) | VAF 143/346 reads (41%) | called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 169/397 reads (43%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- CYP4F12 | c.843G>A p.Q281= | Silent (SNP) | VAF 144/346 reads (42%) | catalogued as COSV100215610; called by muse, mutect2, varscan2
- CYTIP | c.105G>A p.T35= | Silent (SNP) | VAF 146/358 reads (41%) | catalogued as rs760586360; called by muse, mutect2, varscan2
- DELE1 | c.684C>T p.S228= | Silent (SNP) | VAF 125/272 reads (46%) | called by muse, mutect2, varscan2
- DIRAS3 | c.621G>A p.Q207= | Silent (SNP) | VAF 138/336 reads (41%) | called by muse, mutect2, varscan2
- DNAH10 | c.9975G>T p.L3325= (on ENST00000409039; = p.L3264= on NM_207437.3) | Silent (SNP) | VAF 167/365 reads (46%) | called by muse, mutect2, varscan2
- DNAH10 | c.13161G>A p.S4387= (on ENST00000409039; = p.S4326= on NM_207437.3) | Silent (SNP) | VAF 201/494 reads (41%) | catalogued as rs370675426; called by muse, mutect2, varscan2
- DNAH17 | c.3003T>C p.F1001= | Silent (SNP) | VAF 183/404 reads (45%) | catalogued as rs775466290; called by muse, mutect2, varscan2
- DNAH5 | c.10761C>T p.S3587= | Silent (SNP) | VAF 182/401 reads (45%) | catalogued as rs1156933558; called by muse, mutect2, varscan2
- DNAH7 | c.11982G>A p.T3994= | Silent (SNP) | VAF 158/367 reads (43%) | catalogued as rs781492764, COSV56753497; called by muse, mutect2, varscan2
- DOCK3 | c.3564C>A p.S1188= | Silent (SNP) | VAF 180/422 reads (43%) | called by muse, mutect2, varscan2
- DUSP8 | c.1428C>T p.F476= | Silent (SNP) | VAF 618/910 reads (68%) | called by muse, mutect2, varscan2
- EBF1 | c.1656G>A p.V552= | Silent (SNP) | VAF 173/446 reads (39%) | called by muse, mutect2, varscan2
- EMC3 | c.42C>T p.L14= | Silent (SNP) | VAF 156/374 reads (42%) | called by muse, mutect2, varscan2
- EP300 | c.384G>A p.Q128= | Silent (SNP) | VAF 171/555 reads (31%) | catalogued as rs1244840343; called by muse, mutect2, varscan2
- EPPK1 | c.4503G>A p.V1501= | Silent (SNP) | VAF 247/1559 reads (16%) | called by muse, mutect2, varscan2
- FAM187A | c.843G>A p.L281= | Silent (SNP) | VAF 238/545 reads (44%) | catalogued as rs1316120304; called by muse, mutect2, varscan2
- FAM83D | c.1026G>A p.R342= | Silent (SNP) | VAF 205/484 reads (42%) | catalogued as rs1317399360; called by muse, mutect2, varscan2
- FBLN2 | c.2682C>T p.A894= | Silent (SNP) | VAF 139/329 reads (42%) | called by muse, mutect2, varscan2
- FBN3 | c.3750C>T p.L1250= | Silent (SNP) | VAF 124/288 reads (43%) | called by muse, mutect2, varscan2
- FBN3 | c.3087C>T p.I1029= | Silent (SNP) | VAF 122/278 reads (44%) | catalogued as rs267605773; called by muse, mutect2, varscan2
- FCGR2C | c.522C>T p.S174= | Silent (SNP) | VAF 112/510 reads (22%) | catalogued as rs1215720190, COSV100913165; called by muse, mutect2, varscan2
- FLNC | c.6639C>T p.V2213= | Silent (SNP) | VAF 276/670 reads (41%) | catalogued as rs747628268, COSV57961194; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN2 | c.1350C>T p.S450= | Silent (SNP) | VAF 300/709 reads (42%) | catalogued as COSV60424626; called by muse, mutect2, varscan2
- FMO1 | c.885G>A p.G295= | Silent (SNP) | VAF 163/341 reads (48%) | called by muse, mutect2, varscan2
- FOXD4L5 | c.1092C>T p.I364= | Silent (SNP) | VAF 102/852 reads (12%) | called by muse, varscan2
- FYB2 | c.723C>T p.P241= | Silent (SNP) | VAF 163/333 reads (49%) | called by muse, mutect2, varscan2
- FZD8 | c.1593C>T p.I531= | Silent (SNP) | VAF 261/334 reads (78%) | called by muse, mutect2, varscan2
- GABRA1 | c.126C>T p.F42= | Silent (SNP) | VAF 143/347 reads (41%) | catalogued as COSV50102405; called by muse, mutect2, varscan2
- GAK | c.1951C>T p.L651= | Silent (SNP) | VAF 202/497 reads (41%) | called by muse, mutect2, varscan2
- GAPDHS | c.114C>T p.P38= | Silent (SNP) | VAF 211/512 reads (41%) | catalogued as rs770955107; called by muse, mutect2, varscan2
- GCN1 | c.2016C>T p.I672= | Silent (SNP) | VAF 161/405 reads (40%) | catalogued as COSV56104650; called by muse, mutect2, varscan2
- GLT1D1 | c.777G>A p.L259= (on ENST00000442111 / NM_001366889.1; = p.L179= on NM_144669.3) | Silent (SNP) | VAF 113/261 reads (43%) | catalogued as rs927364236; called by muse, mutect2, varscan2
- GPR139 | c.81C>T p.F27= | Silent (SNP) | VAF 230/505 reads (46%) | catalogued as COSV58501474; called by muse, mutect2, varscan2
- GPRC5B | c.141C>T p.S47= | Silent (SNP) | VAF 245/594 reads (41%) | catalogued as rs745928242; called by muse, mutect2, varscan2
- GRIA2 | c.987C>T p.D329= | Silent (SNP) | VAF 131/314 reads (42%) | called by muse, varscan2
- GRID2IP | c.1488C>T p.S496= | Silent (SNP) | VAF 274/570 reads (48%) | called by muse, mutect2, varscan2
- GRM4 | c.2589C>T p.V863= | Silent (SNP) | VAF 460/715 reads (64%) | catalogued as rs1375808367; called by muse, mutect2, varscan2
- GUCY2F | c.1956G>A p.L652= | Silent (SNP) | VAF 128/133 reads (96%) | called by muse, mutect2, varscan2
- GUCY2F | c.1641C>T p.S547= | Silent (SNP) | VAF 160/182 reads (88%) | called by muse, mutect2, varscan2
- H3C4 | c.402G>A p.E134= | Silent (SNP) | VAF 96/299 reads (32%) | called by muse, mutect2, varscan2
- HDC | c.1806C>T p.A602= | Silent (SNP) | VAF 194/488 reads (40%) | called by muse, mutect2, varscan2
- HIPK4 | c.225C>T p.F75= | Silent (SNP) | VAF 164/591 reads (28%) | called by muse, mutect2, varscan2
- HYDIN | c.9208C>T p.L3070= | Silent (SNP) | VAF 105/207 reads (51%) | called by muse, mutect2, varscan2
- ICAM1 | c.1239C>T p.S413= | Silent (SNP) | VAF 158/367 reads (43%) | catalogued as COSV99320827; called by muse, mutect2, varscan2
- IDH3B | c.873C>T p.V291= | Silent (SNP) | VAF 170/468 reads (36%) | catalogued as rs1360163081, COSV61391676; called by muse, mutect2, varscan2
- IGSF3 | c.1380C>T p.I460= (on ENST00000369486 / NM_001007237.3; = p.I480= on NM_001542.4) | Silent (SNP) | VAF 247/552 reads (45%) | called by muse, mutect2, varscan2
- IL27 | c.492G>A p.E164= | Silent (SNP) | VAF 206/483 reads (43%) | called by muse, varscan2
- INPP5E | c.96G>A p.P32= | Silent (SNP) | VAF 330/786 reads (42%) | called by muse, mutect2, varscan2
- IRAG2 | c.174A>G p.E58= | Silent (SNP) | VAF 291/525 reads (55%) | called by muse, mutect2, varscan2
- IRS2 | c.2925C>T p.L975= | Silent (SNP) | VAF 325/741 reads (44%) | called by muse, mutect2, varscan2
- ITK | c.315C>T p.A105= | Silent (SNP) | VAF 92/270 reads (34%) | catalogued as rs1360242669; called by muse, mutect2, varscan2
- ITPR1 | c.4692C>T p.L1564= (on ENST00000354582; = p.L1549= on NM_002222.7) | Silent (SNP) | VAF 180/397 reads (45%) | catalogued as rs375679048; called by muse, mutect2, varscan2
- ITPR3 | c.1689C>T p.S563= | Silent (SNP) | VAF 211/611 reads (35%) | called by muse, mutect2, varscan2
- JAK1 | c.2205C>T p.I735= | Silent (SNP) | VAF 196/445 reads (44%) | catalogued as rs751933525; called by muse, varscan2
- JPH3 | c.1185C>T p.A395= | Silent (SNP) | VAF 155/212 reads (73%) | catalogued as rs201763624; called by muse, mutect2, varscan2
- KANK2 | c.198C>T p.R66= | Silent (SNP) | VAF 248/611 reads (41%) | called by muse, mutect2, varscan2
- KCNB1 | c.1518C>T p.T506= | Silent (SNP) | VAF 180/457 reads (39%) | catalogued as rs775774087; called by muse, mutect2, varscan2
- KCNB2 | c.81T>C p.I27= | Silent (SNP) | VAF 831/1064 reads (78%) | called by muse, mutect2, varscan2
- KCNC3 | c.2193C>T p.P731= | Silent (SNP) | VAF 85/139 reads (61%) | catalogued as rs1252557402; called by muse, mutect2, varscan2
- KCNC4 | c.762C>T p.D254= | Silent (SNP) | VAF 138/307 reads (45%) | called by muse, mutect2, varscan2
- KCNG1 | c.1239C>T p.A413= | Silent (SNP) | VAF 225/504 reads (45%) | called by muse, mutect2, varscan2
- KCNH6 | c.1068C>T p.F356= | Silent (SNP) | VAF 184/646 reads (28%) | catalogued as rs774234991, COSV59003343; called by muse, mutect2, varscan2
- KCP | c.762C>T p.F254= (on ENST00000620378; = p.F311= on NM_001366122.1) | Silent (SNP) | VAF 147/371 reads (40%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1008C>T p.R336= | Silent (SNP) | VAF 235/317 reads (74%) | called by muse, mutect2, varscan2
- KLF6 | c.310C>T p.L104= | Silent (SNP) | VAF 183/223 reads (82%) | called by muse, mutect2, varscan2
- KMT2D | c.7653C>T p.V2551= | Silent (SNP) | VAF 370/627 reads (59%) | called by muse, mutect2, varscan2
- KRTAP10-12 | c.588C>T p.S196= | Silent (SNP) | VAF 329/799 reads (41%) | catalogued as rs372693810; called by muse, varscan2
- KYNU | c.396C>T p.A132= | Silent (SNP) | VAF 46/196 reads (23%) | called by muse, mutect2, varscan2
- LAS1L | c.993C>T p.F331= | Silent (SNP) | VAF 216/240 reads (90%) | catalogued as COSV56706931; called by muse, mutect2, varscan2
- LAYN | c.291C>T p.L97= (on ENST00000375615 / NM_001258390.1; = p.L89= on NM_178834.5) | Silent (SNP) | VAF 158/425 reads (37%) | called by muse, mutect2, varscan2
- LCK | c.357G>A p.A119= | Silent (SNP) | VAF 151/359 reads (42%) | catalogued as rs778915733, COSV60740598; called by muse, mutect2, varscan2
- LHX6 | c.294C>T p.S98= (on ENST00000373755 / NM_001242334.2; = p.S127= on NM_014368.5) | Silent (SNP) | VAF 218/526 reads (41%) | called by muse, mutect2, varscan2
- LIF | c.267C>T p.F89= | Silent (SNP) | VAF 220/473 reads (47%) | called by muse, mutect2, varscan2
- LPA | c.4671G>A p.G1557= | Silent (SNP) | VAF 164/203 reads (81%) | catalogued as COSV60300829; called by muse, mutect2, varscan2
- LRWD1 | c.1365G>A p.P455= | Silent (SNP) | VAF 268/630 reads (43%) | catalogued as rs572272292, COSV52961047, COSV52961789; called by muse, mutect2, varscan2
- LYST | c.10527G>A p.R3509= | Silent (SNP) | VAF 144/357 reads (40%) | catalogued as COSV67704054; called by muse, mutect2, varscan2
- LZIC | c.417G>A p.R139= | Silent (SNP) | VAF 101/282 reads (36%) | catalogued as rs1348206411; called by muse, mutect2, varscan2
- MAGEL2 | c.891G>A p.P297= | Silent (SNP) | VAF 245/572 reads (43%) | catalogued as rs758018158; called by muse, mutect2, varscan2
- MAP1A | c.3216C>T p.A1072= | Silent (SNP) | VAF 153/354 reads (43%) | called by muse, varscan2
- MAPK4 | c.957G>A p.E319= | Silent (SNP) | VAF 239/539 reads (44%) | called by muse, mutect2, varscan2
- MARCHF4 | c.1224G>A p.T408= | Silent (SNP) | VAF 74/180 reads (41%) | catalogued as rs201288119, COSV56104315; called by muse, mutect2, varscan2
- MARCO | c.12G>A p.K4= | Silent (SNP) | VAF 92/211 reads (44%) | catalogued as COSV59052913, COSV59055910; called by muse, mutect2, varscan2
- MGAM2 | c.4824C>T p.F1608= | Silent (SNP) | VAF 165/383 reads (43%) | called by muse, mutect2, varscan2
- MMP13 | c.555G>T p.L185= | Silent (SNP) | VAF 114/294 reads (39%) | called by muse, mutect2, varscan2
- MMP14 | c.1731C>T p.S577= | Silent (SNP) | VAF 167/434 reads (38%) | catalogued as COSV61287472; called by muse, mutect2, varscan2
- MMP28 | c.984C>T p.F328= | Silent (SNP) | VAF 224/491 reads (46%) | catalogued as rs368107958; called by muse, mutect2, varscan2
- MROH2A | c.4389G>A p.G1463= | Silent (SNP) | VAF 221/518 reads (43%) | catalogued as rs774060010; called by muse, mutect2, varscan2
- MS4A4E | c.63G>A p.L21= | Silent (SNP) | VAF 127/324 reads (39%) | called by muse, mutect2, varscan2
- MTNR1A | c.348C>T p.F116= | Silent (SNP) | VAF 173/415 reads (42%) | called by muse, mutect2, varscan2
- MTRES1 | c.705G>A p.K235= | Silent (SNP) | VAF 89/118 reads (75%) | catalogued as rs782521747; called by muse, mutect2, varscan2
- MYH11 | c.2877G>A p.L959= | Silent (SNP) | VAF 168/388 reads (43%) | called by muse, mutect2, varscan2
- MYH2 | c.1629C>T p.F543= | Silent (SNP) | VAF 149/194 reads (77%) | catalogued as rs761000564, COSV99819676; called by muse, mutect2, varscan2
- MYO1F | c.1215C>T p.F405= | Silent (SNP) | VAF 136/300 reads (45%) | catalogued as rs779481404, COSV57793386; called by muse, mutect2, varscan2
- NAGA | c.267C>T p.G89= | Silent (SNP) | VAF 221/861 reads (26%) | catalogued as COSV67169779; called by muse, mutect2, varscan2
- NAGK | c.78C>T p.I26= | Silent (SNP) | VAF 72/193 reads (37%) | called by muse, mutect2, varscan2
- NEB | c.6489G>A p.Q2163= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as rs747215131, COSV51431076; called by muse, mutect2, varscan2
- NEPRO | c.669T>G p.P223= | Silent (SNP) | VAF 148/199 reads (74%) | called by muse, mutect2, varscan2
- NLRP3 | c.855C>T p.I285= | Silent (SNP) | VAF 170/384 reads (44%) | called by muse, mutect2, varscan2
- NLRP7 | c.2862G>A p.V954= (on ENST00000340844 / NM_206828.3; = p.V983= on NM_139176.3) | Silent (SNP) | VAF 160/398 reads (40%) | called by muse, mutect2, varscan2
- NPM3 | c.114C>T p.F38= | Silent (SNP) | VAF 146/182 reads (80%) | catalogued as COSV63380874; called by mutect2, varscan2
- OBSCN | c.15288G>A p.R5096= | Silent (SNP) | VAF 199/484 reads (41%) | called by muse, varscan2
- OCM | c.255C>T p.S85= | Silent (SNP) | VAF 124/334 reads (37%) | catalogued as rs779549074; called by muse, mutect2, varscan2
- OLFML2B | c.1758C>T p.I586= | Silent (SNP) | VAF 193/437 reads (44%) | catalogued as COSV99668368; called by muse, mutect2, varscan2
- OR10G2 | c.48C>T p.F16= | Silent (SNP) | VAF 173/407 reads (43%) | catalogued as COSV73390299; called by muse, mutect2, varscan2
- OR10H4 | c.651C>T p.I217= | Silent (SNP) | VAF 159/390 reads (41%) | catalogued as rs1436466816, COSV59061224; called by muse, mutect2, varscan2
- OR11H2 | c.925C>T p.L309= (on ENST00000556246; = p.L320= on NM_001197287.1) | Silent (SNP) | VAF 64/439 reads (15%) | called by muse, mutect2, varscan2
- OR1S1 | c.585C>T p.A195= | Silent (SNP) | VAF 98/357 reads (27%) | catalogued as rs1172927115; called by muse, mutect2
- OR1S2 | c.585C>T p.A195= | Silent (SNP) | VAF 80/486 reads (16%) | called by muse, varscan2
- OR2V1 | c.552T>C p.A184= | Silent (SNP) | VAF 158/349 reads (45%) | called by muse, mutect2, varscan2
- OR4C15 | c.810C>T p.S270= (on ENST00000314644; = p.S216= on NM_001001920.2) | Silent (SNP) | VAF 193/398 reads (48%) | catalogued as COSV58953246; called by muse, mutect2, varscan2
- OR4K2 | c.855A>T p.I285= | Silent (SNP) | VAF 76/540 reads (14%) | catalogued as COSV100064686; called by muse, mutect2, varscan2
- OR51L1 | c.939G>A p.R313= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as rs1437749839; called by muse, mutect2, varscan2
- OR52B2 | c.27C>T p.F9= | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as rs1280857659; called by muse, varscan2
- OR5T3 | c.696C>T p.F232= | Silent (SNP) | VAF 188/446 reads (42%) | catalogued as COSV100282735, COSV100282964; called by muse, mutect2, varscan2
- OR6N1 | c.153G>A p.L51= | Silent (SNP) | VAF 360/598 reads (60%) | called by muse, mutect2, varscan2
- OSM | c.252G>A p.E84= | Silent (SNP) | VAF 275/664 reads (41%) | called by muse, mutect2, varscan2
- P2RX1 | c.1170G>A p.L390= | Silent (SNP) | VAF 183/234 reads (78%) | catalogued as rs1275545954, COSV99340078; called by muse, mutect2, varscan2
- PAPLN | c.2869C>T p.L957= (on ENST00000554301; = p.L930= on NM_173462.4) | Silent (SNP) | VAF 134/311 reads (43%) | called by muse, mutect2, varscan2
- PBX4 | c.969C>T p.F323= | Silent (SNP) | VAF 148/342 reads (43%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2286C>T p.G762= | Silent (SNP) | VAF 206/423 reads (49%) | called by muse, mutect2, varscan2
- PCSK5 | c.2568C>T p.C856= | Silent (SNP) | VAF 141/330 reads (43%) | catalogued as rs138803714; called by muse, mutect2, varscan2
- PDE6A | c.1680C>T p.N560= | Silent (SNP) | VAF 139/359 reads (39%) | called by muse, mutect2, varscan2
- PLA2G3 | c.39C>T p.F13= | Silent (SNP) | VAF 203/473 reads (43%) | called by muse, mutect2, varscan2
- PLIN1 | c.1356C>T p.P452= | Silent (SNP) | VAF 315/720 reads (44%) | called by muse, mutect2, varscan2
- PLS3 | c.903C>T p.A301= | Silent (SNP) | VAF 125/143 reads (87%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1452C>T p.S484= | Silent (SNP) | VAF 267/345 reads (77%) | called by muse, mutect2, varscan2
- POTEC | c.1104C>T p.I368= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs267605121; called by muse, mutect2, varscan2
- PPIL1 | c.474G>A p.K158= | Silent (SNP) | VAF 114/453 reads (25%) | catalogued as COSV65473085; called by muse, mutect2, varscan2
- PRG4 | c.2193G>A p.K731= | Silent (SNP) | VAF 336/786 reads (43%) | catalogued as COSV63355115; called by muse, mutect2, varscan2
- PRPF40B | c.1695C>T p.I565= (on ENST00000380281; = p.I559= on NM_012272.3) | Silent (SNP) | VAF 162/309 reads (52%) | catalogued as rs150651073; called by muse, mutect2, varscan2
- PSMG3 | c.162C>T p.A54= | Silent (SNP) | VAF 241/286 reads (84%) | called by muse, mutect2, varscan2
- R3HCC1 | c.1278C>T p.T426= (on ENST00000411463; = p.T386= on NM_001136108.3) | Silent (SNP) | VAF 124/154 reads (81%) | called by muse, varscan2
- RAD21L1 | c.897C>T p.L299= | Silent (SNP) | VAF 147/300 reads (49%) | called by muse, mutect2, varscan2
- RALGDS | c.1941C>T p.P647= | Silent (SNP) | VAF 181/420 reads (43%) | catalogued as COSV64429716; called by muse, mutect2, varscan2
- REG1A | c.24C>T p.F8= | Silent (SNP) | VAF 192/450 reads (43%) | catalogued as COSV52068337, COSV52068377; called by muse, mutect2, varscan2
- RGPD3 | c.1503G>A p.K501= | Silent (SNP) | VAF 113/393 reads (29%) | called by muse, mutect2, varscan2
- RHBDF1 | c.423C>T p.P141= | Silent (SNP) | VAF 190/634 reads (30%) | catalogued as COSV99244977; called by muse, mutect2, varscan2
- RICTOR | c.78C>T p.V26= | Silent (SNP) | VAF 154/431 reads (36%) | called by muse, varscan2
- RIMS2 | c.4029G>A p.R1343= | Silent (SNP) | VAF 127/804 reads (16%) | called by muse, mutect2, varscan2
- RINL | c.297C>T p.I99= | Silent (SNP) | VAF 121/434 reads (28%) | called by muse, mutect2, varscan2
- RP1 | c.2793C>T p.F931= | Silent (SNP) | VAF 97/766 reads (13%) | called by muse, mutect2, varscan2
- SCRT2 | c.390G>A p.G130= | Silent (SNP) | VAF 96/189 reads (51%) | catalogued as rs1568651391; called by muse, mutect2, varscan2
- SEPTIN4 | c.310C>T p.L104= | Silent (SNP) | VAF 157/348 reads (45%) | called by muse, mutect2, varscan2
- SERPINA7 | c.1182G>A p.L394= | Silent (SNP) | VAF 191/204 reads (94%) | catalogued as COSV59665521; called by muse, mutect2, varscan2
- SLC13A3 | c.1143C>T p.T381= | Silent (SNP) | VAF 108/310 reads (35%) | catalogued as rs140812730; called by muse, mutect2, varscan2
- SLC30A8 | c.1101C>T p.P367= | Silent (SNP) | VAF 95/714 reads (13%) | catalogued as rs1287611379, COSV69969708; called by muse, mutect2, varscan2
- SLC8A3 | c.2382C>T p.F794= (on ENST00000381269 / NM_183002.3; = p.F792= on NM_033262.4) | Silent (SNP) | VAF 195/468 reads (42%) | catalogued as rs368263429; called by muse, mutect2, varscan2
- SLC9C2 | c.2847G>A p.E949= | Silent (SNP) | VAF 182/428 reads (43%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1167G>A p.L389= | Silent (SNP) | VAF 118/259 reads (46%) | called by muse, mutect2, varscan2
- SMG5 | c.2184C>T p.L728= | Silent (SNP) | VAF 354/607 reads (58%) | called by muse, mutect2, varscan2
- SMIM23 | c.363G>A p.L121= | Silent (SNP) | VAF 154/347 reads (44%) | called by muse, mutect2, varscan2
- SNTG2 | c.228C>T p.L76= | Silent (SNP) | VAF 142/366 reads (39%) | catalogued as COSV57986069; called by muse, mutect2, varscan2
- SOAT1 | c.663C>A p.L221= | Silent (SNP) | VAF 192/448 reads (43%) | catalogued as COSV62654083, COSV62656873; called by muse, mutect2, varscan2
- SOX30 | c.282G>A p.S94= | Silent (SNP) | VAF 18/698 reads (3%) | called by muse, mutect2
- SPATA5L1 | c.639G>A p.R213= | Silent (SNP) | VAF 277/638 reads (43%) | called by muse, mutect2, varscan2
- SSC4D | c.1608C>T p.L536= | Silent (SNP) | VAF 227/519 reads (44%) | catalogued as COSV99300082; called by muse, mutect2, varscan2
- STAT3 | c.1995C>T p.I665= | Silent (SNP) | VAF 162/424 reads (38%) | catalogued as COSV52888488; called by muse, mutect2, varscan2
- STIL | c.897C>T p.F299= | Silent (SNP) | VAF 78/194 reads (40%) | called by muse, mutect2, varscan2
- TACC2 | c.1326G>A p.R442= | Silent (SNP) | VAF 202/267 reads (76%) | called by muse, mutect2, varscan2
- TAF3 | c.945C>T p.S315= | Silent (SNP) | VAF 227/283 reads (80%) | called by muse, mutect2, varscan2
- TANC2 | c.3375C>T p.S1125= | Silent (SNP) | VAF 88/356 reads (25%) | called by muse, mutect2, varscan2
- TATDN2 | c.1953G>A p.K651= | Silent (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- TFEB | c.996C>T p.S332= | Silent (SNP) | VAF 500/819 reads (61%) | called by muse, mutect2, varscan2
- THRB | c.1206C>T p.A402= | Silent (SNP) | VAF 168/401 reads (42%) | called by muse, mutect2, varscan2
- THSD1 | c.2412C>T p.P804= | Silent (SNP) | VAF 129/290 reads (44%) | catalogued as rs776907289; called by muse, mutect2, varscan2
- TJP3 | c.885G>A p.S295= | Silent (SNP) | VAF 234/537 reads (44%) | catalogued as rs553055182; called by muse, mutect2, varscan2
- TMC5 | c.1068C>T p.S356= (on ENST00000396229 / NM_001105248.1; = p.S110= on NM_024780.5) | Silent (SNP) | VAF 96/212 reads (45%) | catalogued as COSV54901234; called by muse, mutect2
- TMEM132B | c.1317G>A p.K439= | Silent (SNP) | VAF 141/377 reads (37%) | catalogued as COSV54765855; called by muse, mutect2, varscan2
- TMEM14B | c.264C>T p.F88= | Silent (SNP) | VAF 163/572 reads (28%) | catalogued as COSV101077475; called by muse, mutect2, varscan2
- TMEM176A | c.462C>T p.S154= | Silent (SNP) | VAF 200/435 reads (46%) | called by muse, mutect2, varscan2
- TMEM8B | c.54C>T p.S18= | Silent (SNP) | VAF 338/762 reads (44%) | catalogued as rs762579513, COSV65077986; called by muse, mutect2, varscan2
- TMPRSS13 | c.1188C>T p.S396= | Silent (SNP) | VAF 168/412 reads (41%) | called by muse, varscan2
- TRAV26-1 | c.132C>T p.I44= | Silent (SNP) | VAF 172/374 reads (46%) | called by muse, mutect2, varscan2
- VPS13B | c.6351G>A p.K2117= | Silent (SNP) | VAF 593/904 reads (66%) | called by muse, mutect2, varscan2
- VPS13C | c.7836G>A p.K2612= (on ENST00000644861 / NM_020821.3; = p.K2569= on NM_017684.5) | Silent (SNP) | VAF 152/360 reads (42%) | called by muse, varscan2
- WDR70 | c.1176C>T p.V392= | Silent (SNP) | VAF 111/244 reads (45%) | catalogued as rs1326288676; called by muse, mutect2, varscan2
- XCR1 | c.282C>T p.G94= | Silent (SNP) | VAF 169/415 reads (41%) | called by muse, mutect2, varscan2
- YIPF6 | c.138C>T p.I46= | Silent (SNP) | VAF 176/194 reads (91%) | catalogued as COSV65856224; called by muse, mutect2, varscan2
- ZBTB46 | c.1095C>T p.T365= | Silent (SNP) | VAF 276/628 reads (44%) | catalogued as rs759299672, COSV55513971; called by muse, mutect2, varscan2
- ZFAT | c.2340C>A p.I780= | Silent (SNP) | VAF 302/1009 reads (30%) | called by muse, mutect2, varscan2
- ZFP57 | c.1113C>T p.S371= | Silent (SNP) | VAF 289/1018 reads (28%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1350G>A p.T450= | Silent (SNP) | VAF 884/1150 reads (77%) | catalogued as rs951468447, COSV65874594; called by muse, mutect2, varscan2
- ZNF688 | c.72G>T p.G24= | Silent (SNP) | VAF 306/1008 reads (30%) | called by muse, mutect2, varscan2
- ABCD1 | c.1081+22G>A | Intron (SNP) | VAF 296/349 reads (85%) | called by muse, mutect2, varscan2
- ADRA2B | c.*1598G>A | 3'UTR (SNP) | VAF 115/312 reads (37%) | called by muse, mutect2, varscan2
- ATAD3B | c.*286G>A | 3'UTR (SNP) | VAF 122/227 reads (54%) | called by muse, mutect2, varscan2
- CD6 | c.*875C>T | 3'UTR (SNP) | VAF 148/409 reads (36%) | called by muse, mutect2, varscan2
- DNAH14 | c.5584+5656C>T | Intron (SNP) | VAF 135/295 reads (46%) | called by muse, mutect2, varscan2
- GNAS | chr20:58850555 C>T | 5'Flank (SNP) | VAF 106/247 reads (43%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+620C>T | Intron (SNP) | VAF 76/369 reads (21%) | catalogued as rs1442834717; called by muse, varscan2
- ISCA2P1 | chr22:26646829 G>A | 5'Flank (SNP) | VAF 176/448 reads (39%) | called by muse, varscan2
- JAKMIP1 | chr4:6049827 C>T | 3'Flank (SNP) | VAF 124/288 reads (43%) | catalogued as rs1274174883, COSV51524978; called by muse, mutect2, varscan2
- KCNH7 | c.2154+18C>T | Intron (SNP) | VAF 158/361 reads (44%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22041C>T | Intron (SNP) | VAF 109/399 reads (27%) | catalogued as rs1159913886; called by muse, mutect2, varscan2
- KLHL9 | c.-431G>A | 5'UTR (SNP) | VAF 256/551 reads (46%) | called by muse, mutect2, varscan2
- MGAM | c.4619-12132C>T | Intron (SNP) | VAF 112/304 reads (37%) | catalogued as rs1374095421; called by muse, mutect2, varscan2
- MLIP | c.613-11063C>T | Intron (SNP) | VAF 246/747 reads (33%) | called by muse, mutect2, varscan2
- OR10J1 | c.-19C>T | 5'UTR (SNP) | VAF 105/353 reads (30%) | catalogued as COSV71129676; called by muse, mutect2, varscan2
- OR2T8 | chr1:247921017 C>T | 5'Flank (SNP) | VAF 92/198 reads (46%) | catalogued as COSV100178398; called by muse, varscan2
- PRRG3 | c.168+9C>T | Intron (SNP) | VAF 265/294 reads (90%) | called by muse, mutect2, varscan2
- SCNN1B | c.-9+21120G>A | Intron (SNP) | VAF 143/338 reads (42%) | called by muse, mutect2, varscan2
- TMC5 | c.1049-3496C>T | Intron (SNP) | VAF 101/255 reads (40%) | catalogued as COSV54903009; called by muse, mutect2, varscan2
- TMEM99 | n.541C>T | RNA (SNP) | VAF 218/498 reads (44%) | called by muse, mutect2
- TTN | c.10361-4254C>T | Intron (SNP) | VAF 109/288 reads (38%) | called by muse, mutect2, varscan2
- VIPR2 | c.357+6685C>T | Intron (SNP) | VAF 279/687 reads (41%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2285C>T | Intron (SNP) | VAF 181/640 reads (28%) | called by muse, mutect2, varscan2
